CPTAC case C3L-04354 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/db9021f9-df04-48c4-b56c-499f49c5212f

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 60.3 years (22,041 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,393 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,393 days (3.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm (a second GDC size field records 2.4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: No; Vascular invasion present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (5 entries)
- Days to follow up: 408 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 758 days (2.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,017 days (2.8 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,017 days (2.8 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,393 days (3.8 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 85 kg; Height: 180 cm; BMI: 26.23.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 9; Cigarettes per day: 6; Tobacco smoking onset year: 1988; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 34.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04354-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 150 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04354-22: Section location: Larynx; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-04354-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 114 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-04354-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 70 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-04354-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
